TCGA case TCGA-WA-A7GZ — Head and Neck Squamous Cell Carcinoma (TCGA-HNSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Floor of mouth; Tissue source site: University of Schleswig-Holstein. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/f9e82d62-fafc-45b0-97cf-d1a4a3c884a1

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Germany; Age at index: 58 years; Vital status: Dead; Days to death: 625 days (1.7 years); Cause of death: Not Cancer Related.

Diagnoses (1)
1. Squamous cell carcinoma, keratinizing, NOS: ICD-O-3 morphology code: 8071/3; ICD-10 code: C04.9; Tissue or organ of origin: Floor of mouth, NOS; Site of resection or biopsy: Head, face or neck, NOS; Classification of tumor: primary; Age at diagnosis: 58.1 years (21,207 days); Year of diagnosis: 2012; AJCC staging edition: 7th; AJCC clinical T: T2; AJCC clinical N: N0; AJCC clinical M: M0; AJCC clinical stage: Stage II; AJCC pathologic T: T2; AJCC pathologic N: N0; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 625 days (1.7 years).
   Pathology details: Consistent pathology review: Yes; Margin status: Uninvolved.
   Pathology details: Lymph node dissection method: Functional (Limited) Neck Dissection; Lymph node dissection site: Neck, Left.
   Pathology details: Lymph node dissection method: Functional (Limited) Neck Dissection; Lymph node dissection site: Neck, Right.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response.

Follow-up (2 entries)
- Days to follow up: 335 days; Disease response: Tumor Free.
- Days to follow up: 625 days (1.7 years); Disease response: Tumor Free.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 20; Tobacco smoking onset year: 1984.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-WA-A7GZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Initial weight: 60 mg.
  Slide TCGA-WA-A7GZ-01A-01-TS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 20; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-WA-A7GZ-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-WA-A7GZ-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample TCGA-WA-A7GZ-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Initial weight: 80 mg.
  Slide TCGA-WA-A7GZ-11A-01-TS1: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Head and Neck; Histologic diagnosis: Head & Neck Squamous Cell Carcinoma; Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: Tumor free; Lymph nodes examined: Yes; Lymph node neck dissection indicator: Yes; Margin status: Negative; Tobacco smoking history indicator: 2; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response; Tobacco smokeless use at diagnosis: No; Tobacco smokeless regular use: No; Cause of death: Other, non-malignant disease; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 625 days; disease-specific survival: no event (censored), 625 days; disease-free interval: no event (censored), 625 days; progression-free interval: no event (censored), 625 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-WA-A7GZ-01A-11D-A34I-01): tumor purity 0.43, ploidy 3.53, whole-genome doublings 1.
